Somatic mutation profile of tumor specimen TCGA-S9-A7IS-01A (aliquot TCGA-S9-A7IS-01A-11D-A34A-08) from TCGA case TCGA-S9-A7IS, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 34.0 years (12,402 days).
Specimen TCGA-S9-A7IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa96970e-b083-435f-88fe-d9d7fca4cfbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7IS-10A (Blood Derived Normal), aliquot TCGA-S9-A7IS-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bed3fb1-6145-49e9-bf90-53ae6a5bef0b

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HBB | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1141387, CM033781, CM800011, HM971912, COSV100092842; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 44/111 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PDGFRA | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 1143/2010 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99957204; called by muse, mutect2, varscan2
- ABCA4 | c.6142G>A p.E2048K | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs755513058, COSV64672956; called by muse, mutect2, varscan2
- ADAM2 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765710108, COSV99697651; called by muse, mutect2, varscan2
- AHNAK | c.5020T>C p.S1674P | Missense Mutation (SNP) | VAF 104/460 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV99948559; called by muse, mutect2, varscan2
- CD93 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs779569738, COSV55665675, COSV55667177, COSV99849651; called by muse, mutect2, varscan2
- CEMIP2 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV100987446; called by muse, mutect2
- CHD9 | c.3955C>T p.R1319* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | catalogued as COSV99529447; called by muse, mutect2
- DCDC1 | c.960+2T>C p.X320_splice | Splice Site (SNP) | VAF 40/87 reads (46%) | catalogued as rs1054897157, COSV100663872; called by muse, mutect2, varscan2
- EPHA7 | c.2453A>G p.D818G | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100994025; called by muse, mutect2, varscan2
- FREM2 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1187549141, COSV54855782; called by muse, mutect2, varscan2
- GABRG3 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1471042419, COSV61514312, COSV61529275; called by muse, mutect2, varscan2
- GTF2H2C | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV101053401; called by mutect2, varscan2
- HBG2 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs587776864, CM112986, COSV100400674; called by muse, mutect2, varscan2
- HJURP | c.346A>G p.S116G | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100982617; called by muse, mutect2, varscan2
- HPSE2 | c.1660A>T p.T554S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100986029, COSV65181859; called by muse, varscan2
- IGSF1 | c.2879T>C p.L960P | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100812200; called by muse, mutect2, varscan2
- IL12RB2 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.815); catalogued as rs752262539, COSV99255432; called by muse, mutect2
- ITGB6 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140624114; called by muse, mutect2, varscan2
- LYSMD4 | c.502G>A p.G168S (on ENST00000409796 / NM_001284417.2; = p.G169S on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100230662; called by muse, mutect2, varscan2
- MACF1 | c.21821A>C p.H7274P (on ENST00000372915; = p.H5319P on NM_012090.5) | Missense Mutation (SNP) | VAF 11/218 reads (5%) | catalogued as COSV99245754; called by muse, mutect2
- MNDA | c.949T>C p.S317P | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.213); catalogued as COSV63742416; called by muse, mutect2, varscan2
- MYO10 | c.3995C>T p.T1332I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99945890; called by muse, varscan2
- NPAP1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs749766364, COSV100275741; called by muse, varscan2
- OR2T4 | c.529T>C p.S177P | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100822546, COSV63545437; called by muse, mutect2, varscan2
- PCF11 | c.1791G>A p.W597* | Nonsense Mutation (SNP) | VAF 32/89 reads (36%) | catalogued as COSV100018842; called by muse, mutect2, varscan2
- PDE6B | c.2120A>T p.E707V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99728050; called by muse, mutect2, varscan2
- PDGFRA | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 165/1338 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV57275011; called by muse, mutect2, varscan2
- RNF113A | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 106/276 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101007087; called by muse, mutect2, varscan2
- SCN10A | c.5587C>T p.R1863W | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370779258; called by muse, mutect2, varscan2
- SI | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1428341066, COSV52279476; called by muse, mutect2, varscan2
- SPATC1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs1321826500, COSV66298022; called by muse, mutect2, varscan2
- STAM | c.1425C>G p.S475R | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV101098243; called by muse, mutect2, varscan2
- SYNCRIP | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV100784275; called by muse, mutect2, varscan2
- TLL1 | c.118A>G p.N40D | Missense Mutation (SNP) | VAF 102/153 reads (67%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV99286437, COSV99287972; called by muse, mutect2, varscan2
- TSGA13 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1364116704, COSV100746860; called by muse, mutect2, varscan2
- WNK1 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100267939; called by muse, mutect2, varscan2
- ARID2 | c.159_160del p.R53Sfs*12 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | called by pindel, varscan2
- ATRX | c.3904del p.R1302Efs*44 | Frame Shift Del (DEL) | VAF 66/171 reads (39%) | called by mutect2, pindel, varscan2
- UBQLN1 | c.684_692del p.M228_N231delinsI | In Frame Del (DEL) | VAF 39/89 reads (44%) | called by mutect2, pindel, varscan2
- CAMSAP1 | c.3303C>T p.S1101= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs200971914, COSV100410197; called by muse, mutect2, varscan2
- CHST11 | c.810C>T p.H270= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100359705; called by muse, mutect2, varscan2
- FAT1 | c.7485C>T p.N2495= | Silent (SNP) | VAF 127/168 reads (76%) | catalogued as rs775884355, COSV71671621; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLK12 | c.333G>T p.L111= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV99142011; called by muse, mutect2, varscan2
- LILRA4 | c.414C>T p.N138= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs138743259; called by muse, mutect2, varscan2
- OCA2 | c.735G>A p.G245= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV62345061; called by muse, mutect2, varscan2
- P2RY8 | c.66C>T p.I22= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs747081444, COSV101184109; called by muse, mutect2, varscan2
- RET | c.1122G>A p.V374= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100394086; called by muse, mutect2, varscan2
- SEL1L2 | c.1056G>A p.P352= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as rs773756757, COSV53149775, COSV53158088; called by muse, mutect2, varscan2
- SLC9C2 | c.1068G>C p.V356= | Silent (SNP) | VAF 7/198 reads (4%) | catalogued as COSV100876895; called by muse, mutect2
- ZSCAN10 | c.1194G>A p.A398= (on ENST00000252463; = p.A453= on NM_032805.3) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs773669972, COSV99374198; called by muse, mutect2, varscan2
- XIST | n.11088G>T | RNA (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
